Somatic mutation profile of tumor specimen TCGA-P4-A5EB-01A (aliquot TCGA-P4-A5EB-01A-11D-A28G-10) from TCGA case TCGA-P4-A5EB, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-P4-A5EB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4fec491-30db-480f-968b-84eb1ce2ff30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P4-A5EB-11A (Solid Tissue Normal), aliquot TCGA-P4-A5EB-11A-11D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8199f311-4c84-443c-a93d-4e9f407c65a1

The open-access MAF lists 146 somatic variants for this specimen: 113 protein-altering or splice-affecting, 29 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 29, Frame Shift Del 16, Nonsense Mutation 6, Splice Site 3, Intron 3, Splice Region 2, Frame Shift Ins 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.4156G>C p.E1386Q | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.069); catalogued as rs755216595, COSV66071433; called by muse, mutect2, varscan2
- AGO3 | c.1304T>A p.V435E | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as COSV55797683; called by muse, mutect2
- AKAP9 | c.3050G>A p.S1017N | Missense Mutation (SNP) | VAF 79/136 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.238); catalogued as COSV62359159; called by muse, mutect2, varscan2
- AKT3 | c.561G>A p.K187= | Splice Region (SNP) | VAF 6/39 reads (15%) | catalogued as COSV55635479, COSV55638647; called by muse, mutect2, varscan2
- ANKK1 | c.535A>C p.I179L | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.566); catalogued as COSV58274632; called by muse, mutect2, varscan2
- APAF1 | c.2305-2A>C p.X769_splice (on ENST00000551964 / NM_181861.2; = p.X758_splice on NM_001160.3) | Splice Site (SNP) | VAF 21/56 reads (38%) | catalogued as COSV59669111; called by muse, mutect2, varscan2
- B4GALNT3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs763923882, COSV56758737; called by muse, mutect2, varscan2
- BMP15 | c.340A>T p.I114L | Missense Mutation (SNP) | VAF 99/104 reads (95%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV53142259; called by muse, mutect2, varscan2
- CASZ1 | c.4255G>T p.A1419S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.413); catalogued as COSV65461663; called by muse, mutect2, varscan2
- CBLB | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51438266; called by muse, mutect2, varscan2
- CETP | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs144949752; called by muse, mutect2, varscan2
- CLK4 | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 53/123 reads (43%) | catalogued as COSV60321444; called by muse, mutect2, varscan2
- COX10 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55409526; called by muse, mutect2, varscan2
- CSAD | c.1055A>G p.K352R (on ENST00000444623 / NM_001244705.2; = p.K379R on NM_015989.5) | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs777136216, COSV57245250; called by muse, mutect2, varscan2
- CSMD2 | c.8344C>A p.H2782N | Missense Mutation (SNP) | VAF 96/169 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53970033; called by muse, mutect2, varscan2
- CSMD3 | c.2777A>C p.E926A (on ENST00000297405 / NM_001363185.1; = p.E822A on NM_052900.3) | Missense Mutation (SNP) | VAF 84/131 reads (64%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52337570; called by muse, mutect2, varscan2
- CUL9 | c.1672A>G p.S558G | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV52735742; called by muse, mutect2, varscan2
- DHRS7C | c.466A>T p.I156F (on ENST00000330255 / NM_001220493.2; = p.I155F on NM_001105571.3) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57653044; called by muse, mutect2
- DMD | c.6185C>A p.A2062E | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV63797743; called by muse, mutect2, varscan2
- DNAH1 | c.10667T>C p.I3556T | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV70237385; called by muse, mutect2, varscan2
- DYNC1H1 | c.6647T>C p.I2216T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV64143649; called by muse, mutect2, varscan2
- EAF2 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56546362; called by muse, mutect2
- EIF4G2 | c.2454A>C p.K818N | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.606); catalogued as COSV60599401; called by muse, mutect2, varscan2
- ERLEC1 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51753851; called by muse, mutect2, varscan2
- EXOC7 | c.1820C>T p.S607F (on ENST00000335146 / NM_001145297.4; = p.S525F on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.496); catalogued as rs891827951, COSV58037830; called by muse, mutect2
- EYA2 | c.1105G>C p.G369R | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100426876; called by mutect2, varscan2
- FBXO6 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV65101393; called by muse, mutect2, varscan2
- FNIP1 | c.2176G>A p.G726R | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as rs367969091; called by muse, mutect2, varscan2
- GCA | c.244A>C p.I82L | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.674); catalogued as COSV52026914, COSV52026966; called by muse, mutect2, varscan2
- GNAI3 | c.487T>G p.S163A | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63984637; called by muse, mutect2, varscan2
- GNG12 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0.131); catalogued as COSV63974387; called by muse, mutect2, varscan2
- HECA | c.782del p.G261Vfs*38 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as COSV62769096, COSV62770349; called by mutect2, pindel, varscan2
- HELZ | c.4336G>A p.E1446K | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs1457290825, COSV62381289; called by muse, mutect2, varscan2
- HTT | c.3802C>T p.R1268C | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs779780620, COSV61870548; called by muse, mutect2, varscan2
- IQGAP2 | c.3632C>T p.S1211L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV57172440; called by muse, mutect2, varscan2
- ITGB3BP | c.29A>C p.D10A | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV52130975, COSV52135890; called by muse, varscan2
- JUP | c.321G>C p.E107D | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60278940, COSV60280110; called by muse, mutect2, varscan2
- KCNA2 | c.314C>G p.P105R | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60371662; called by muse, mutect2, varscan2
- KCNH3 | c.1883A>C p.E628A | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57793304; called by muse, mutect2, varscan2
- KCNK15 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1198139934, COSV65720907; called by muse, mutect2, varscan2
- KCNN3 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV55228186; called by muse, mutect2, varscan2
- KCNS3 | c.888G>C p.R296S | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58409122; called by muse, mutect2, varscan2
- KEAP1 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 87/99 reads (88%) | catalogued as rs1568401513, COSV50655012; called by muse, mutect2, varscan2
- KHK | c.111G>T p.W37C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV53157764; called by muse, mutect2, varscan2
- KRT38 | c.254T>G p.I85S | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.963); catalogued as COSV55847870; called by muse, mutect2, varscan2
- LHX3 | c.967G>A p.A323T (on ENST00000371748 / NM_178138.6; = p.A328T on NM_014564.5) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as rs965091161; called by muse, varscan2
- LRR1 | c.1072G>T p.V358F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV53565223; called by muse, mutect2, varscan2
- LRRCC1 | c.3004G>T p.E1002* | Nonsense Mutation (SNP) | VAF 69/252 reads (27%) | catalogued as COSV64486208; called by muse, mutect2, varscan2
- LRTM2 | c.268A>T p.N90Y | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV54566908; called by muse, mutect2, varscan2
- MACF1 | c.15238G>C p.G5080R (on ENST00000372915; = p.G3013R on NM_012090.5) | Missense Mutation (SNP) | VAF 38/127 reads (30%) | catalogued as COSV57147678; called by muse, mutect2, varscan2
- MAP3K19 | c.2370G>C p.Q790H | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV59642696; called by muse, mutect2, varscan2
- MBOAT7 | c.434A>T p.D145V | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV55477948; called by muse, mutect2, varscan2
- METTL22 | c.982T>C p.C328R | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs1338809697; called by muse, mutect2, varscan2
- METTL5 | c.225-1G>T p.X75_splice | Splice Site (SNP) | VAF 38/109 reads (35%) | catalogued as COSV53628046; called by muse, mutect2, varscan2
- MLEC | c.602del p.D201Afs*96 | Frame Shift Del (DEL) | VAF 61/161 reads (38%) | catalogued as COSV57329681; called by mutect2, pindel, varscan2
- NAGK | c.782A>G p.K261R | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54904737; called by muse, mutect2, varscan2
- NCAM2 | c.2366A>T p.N789I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as COSV53106949; called by muse, mutect2, varscan2
- NHEJ1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237050535, COSV55409868; called by muse, mutect2, varscan2
- NLRC3 | c.615C>G p.S205R | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV57096525; called by muse, mutect2, varscan2
- NSD1 | c.6651G>T p.E2217D | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV61785994; called by muse, mutect2, varscan2
- OPTN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 93/164 reads (57%) | catalogued as COSV53813675; called by muse, mutect2, varscan2
- OR51D1 | c.623A>T p.N208I | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV62914930; called by muse, mutect2, varscan2
- OXA1L | c.1285T>A p.W429R (on ENST00000285848; = p.W369R on NM_005015.5) | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53538699; called by muse, mutect2, varscan2
- PARP14 | c.4076C>G p.S1359* | Nonsense Mutation (SNP) | VAF 97/173 reads (56%) | catalogued as COSV71735677; called by muse, mutect2, varscan2
- PTPRJ | c.526T>G p.L176V | Missense Mutation (SNP) | VAF 122/303 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV69254959; called by muse, mutect2, varscan2
- PTPRS | c.70G>T p.V24F | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as COSV53639724, COSV99508774; called by muse, mutect2, varscan2
- RBP2 | c.16A>T p.N6Y | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV51674966; called by muse, mutect2, varscan2
- RCOR3 | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1368394054, COSV65366427, COSV65367066; called by muse, mutect2, varscan2
- REEP5 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV54845039; called by muse, mutect2, varscan2
- RFC4 | c.824A>T p.D275V | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV56215587, COSV56218937; called by muse, mutect2, varscan2
- RNF20 | c.183G>C p.M61I | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV66355603, COSV66355906; called by muse, mutect2, varscan2
- RNF216 | c.350C>G p.S117* (on ENST00000425013 / NM_207116.3; = p.S174* on NM_207111.4) | Nonsense Mutation (SNP) | VAF 71/140 reads (51%) | catalogued as COSV66289641; called by muse, mutect2, varscan2
- RPL7A | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV59300381; called by muse, mutect2, varscan2
- SETD5 | c.130A>G p.N44D | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.115); catalogued as COSV56718009; called by muse, mutect2, varscan2
- SHANK3 | c.4034C>T p.A1345V | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.644); catalogued as rs1440628723, COSV53192008; called by muse, mutect2, varscan2
- SLC7A9 | c.779T>C p.I260T | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50095753; called by muse, mutect2, varscan2
- SMARCC2 | c.516C>A p.N172K | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV57225742; called by muse, mutect2, varscan2
- SPC25 | c.19G>C p.A7P | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV56369900, COSV56371106; called by muse, mutect2, varscan2
- SPON1 | c.348C>T p.I116= | Splice Region (SNP) | VAF 23/70 reads (33%) | catalogued as COSV59969359; called by muse, mutect2, varscan2
- SSMEM1 | c.461A>T p.E154V | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV52834530; called by muse, mutect2, varscan2
- SV2B | c.1319T>A p.I440N | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV57702782; called by muse, mutect2
- SYNPO2 | c.2777A>T p.N926I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61118743; called by muse, mutect2, varscan2
- TLN1 | c.3995A>T p.K1332M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV59212308; called by muse, mutect2, varscan2
- TNXB | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV64490157; called by muse, mutect2
- TRIM69 | c.484-1G>C p.X162_splice (on ENST00000329464 / NM_182985.5; = p.X3_splice on NM_080745.5) | Splice Site (SNP) | VAF 53/119 reads (45%) | catalogued as COSV57805613; called by muse, mutect2, varscan2
- TSHZ3 | c.1605C>A p.N535K | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53684594; called by muse, mutect2, varscan2
- UBE3D | c.264A>C p.K88N | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV52758026; called by muse, mutect2, varscan2
- UGGT1 | c.4258G>T p.V1420L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52142578; called by muse, mutect2, varscan2
- UGGT2 | c.221T>C p.L74S | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as COSV65026148; called by muse, mutect2, varscan2
- WTIP | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as rs769030142, COSV54330776, COSV99542494; called by muse, mutect2, varscan2
- XIRP2 | c.3685C>G p.H1229D (on ENST00000628543; = p.H1404D on NM_152381.6) | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV54738385; called by muse, mutect2, varscan2
- ZBTB7B | c.96C>G p.H32Q (on ENST00000292176; = p.H66Q on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV52695122; called by muse, mutect2, varscan2
- ZC2HC1C | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53173337; called by muse, mutect2, varscan2
- ZNF518A | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 111/204 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60152691, COSV60153670; called by muse, mutect2, varscan2
- ZNF654 | c.2991T>G p.I997M | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58807505; called by muse, mutect2, varscan2
- AL358113.1 | c.3956dup p.L1319Ffs*5 | Frame Shift Ins (INS) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- DNAH8 | c.4585_4602del p.I1529_R1534del | In Frame Del (DEL) | VAF 39/83 reads (47%) | called by mutect2, pindel, varscan2
- FCGBP | c.11965C>A p.L3989M | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HPS3 | c.314_315dup p.I106Vfs*4 | Frame Shift Ins (INS) | VAF 27/114 reads (24%) | called by mutect2, varscan2
- MAST2 | c.2732_2733del p.S911* | Frame Shift Del (DEL) | VAF 46/85 reads (54%) | called by mutect2, pindel, varscan2
- OFD1 | c.431del p.L144* | Frame Shift Del (DEL) | VAF 205/243 reads (84%) | called by mutect2, varscan2
- PCSK9 | c.1920del p.T641Pfs*10 | Frame Shift Del (DEL) | VAF 105/227 reads (46%) | called by mutect2, pindel, varscan2
- PPP2R5E | c.485del p.L162Wfs*15 | Frame Shift Del (DEL) | VAF 44/100 reads (44%) | called by mutect2, pindel, varscan2
- RAPH1 | c.3138_3139del p.A1048Kfs*24 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | called by pindel, varscan2
- RBAK | c.1463del p.S488Mfs*19 | Frame Shift Del (DEL) | VAF 46/107 reads (43%) | called by mutect2, pindel, varscan2
- RCHY1 | c.503del p.L168Yfs*10 | Frame Shift Del (DEL) | VAF 109/235 reads (46%) | called by mutect2, pindel, varscan2
- RUSC2 | c.1357del p.V453Sfs*9 | Frame Shift Del (DEL) | VAF 46/93 reads (49%) | called by mutect2, pindel, varscan2
- SPEG | c.8320_8324del p.S2775Cfs*22 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | called by mutect2, pindel, varscan2
- TLN1 | c.6931_6937del p.G2311Qfs*11 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- TWF2 | c.283_295del p.V95Cfs*10 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | called by mutect2, pindel*, varscan2*
- UBQLN2 | c.1786_1787del p.N596Pfs*2 | Frame Shift Del (DEL) | VAF 126/183 reads (69%) | called by mutect2, pindel, varscan2
- VSTM2A | c.112del p.A38Rfs*64 | Frame Shift Del (DEL) | VAF 43/160 reads (27%) | called by mutect2, pindel, varscan2
- ZBTB38 | c.823_829del p.S275Qfs*14 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | called by mutect2, pindel, varscan2
- AADACL4 | c.264G>T p.V88= | Silent (SNP) | VAF 60/110 reads (55%) | catalogued as COSV66107328; called by muse, mutect2, varscan2
- ABHD6 | c.57A>T p.P19= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV55910646; called by muse, mutect2, varscan2
- ARAP2 | c.2844C>A p.I948= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV58282373; called by muse, mutect2, varscan2
- ARHGAP33 | c.3114C>T p.P1038= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs182833371, COSV50180918; called by muse, mutect2, varscan2
- CILP | c.1155G>T p.V385= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV56028425; called by muse, mutect2, varscan2
- CKAP5 | c.2847C>G p.V949= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV56374892; called by muse, mutect2, varscan2
- COQ3 | c.699A>T p.T233= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV54642388; called by muse, mutect2, varscan2
- CREBBP | c.6030G>A p.G2010= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1335546261, COSV52143208; called by muse, mutect2, varscan2
- DCLK1 | c.1734T>C p.Y578= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV55214181; called by muse, mutect2, varscan2
- EFS | c.769C>T p.L257= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs1365636525, COSV53734474, COSV99391713; called by muse, mutect2, varscan2
- ERN2 | c.1140G>A p.L380= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV56838508; called by muse, varscan2
- FBN1 | c.5319C>A p.I1773= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV57332271; called by muse, mutect2, varscan2
- GPR84 | c.987C>T p.A329= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as COSV57210504; called by muse, mutect2
- HIPK2 | c.3210G>T p.P1070= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1224985166, COSV101301661, COSV69212420; called by muse, mutect2, varscan2
- LATS1 | c.2640G>C p.G880= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV53601170; called by muse, mutect2, varscan2
- LSR | c.1305C>A p.T435= (on ENST00000361790; = p.T416= on NM_015925.6) | Silent (SNP) | VAF 83/141 reads (59%) | catalogued as rs1402811513, COSV55888489; called by muse, mutect2, varscan2
- METTL1 | c.60C>T p.Y20= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV55745885; called by muse, varscan2
- NUP160 | c.1476T>C p.S492= | Silent (SNP) | VAF 163/335 reads (49%) | catalogued as COSV65856350; called by muse, mutect2, varscan2
- NUP62 | c.69G>A p.T23= | Silent (SNP) | VAF 45/77 reads (58%) | catalogued as rs767316682, COSV61313905; called by muse, mutect2, varscan2
- PACS2 | c.477C>T p.I159= | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as COSV57657800; called by muse, mutect2, varscan2
- PLAA | c.741G>T p.V247= | Silent (SNP) | VAF 45/76 reads (59%) | catalogued as COSV68305720; called by muse, mutect2, varscan2
- PLD1 | c.1923C>T p.T641= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV60574931; called by muse, mutect2, varscan2
- R3HDM2 | c.1275A>G p.P425= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as COSV100715219; called by muse, mutect2, varscan2
- RHD | c.714G>A p.V238= | Silent (SNP) | VAF 116/126 reads (92%) | catalogued as rs1415798669, COSV59647487; called by muse, mutect2, varscan2
- RPGRIP1 | c.402C>T p.A134= | Silent (SNP) | VAF 54/218 reads (25%) | catalogued as COSV52858612; called by muse, mutect2, varscan2
- SETBP1 | c.3939C>T p.D1313= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as COSV56338671; called by muse, mutect2, varscan2
- TRBV20-1 | c.335A>G p.*112= | Silent (SNP) | VAF 49/75 reads (65%) | called by muse, mutect2, varscan2
- WBP11 | c.1293T>C p.P431= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV53765082; called by muse, mutect2, varscan2
- ZNF655 | c.79C>T p.L27= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV53160385; called by muse, mutect2, varscan2
- AKT2 | c.-85+2622del | Intron (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- BACE2 | c.312+10929C>T | Intron (SNP) | VAF 44/159 reads (28%) | catalogued as COSV57744334; called by muse, mutect2, varscan2
- PKHD1 | c.10156+22388A>C | Intron (SNP) | VAF 32/76 reads (42%) | catalogued as COSV100583207; called by muse, mutect2
- STAG3L4 | n.616T>G | RNA (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
